TARGET case TARGET-30-PALYLZ — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/7287832f-9473-53dc-855a-023f764cb46d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 1.3 years (488 days); Year of diagnosis: 2002; Days to last follow up: 3,083 days (8.4 years); INSS stage: Stage 1.

Biospecimens (2 samples)
- Sample TARGET-30-PALYLZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PALYLZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
